CCDI case PBCIDV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ec3fd852-6ee5-4349-88a5-c6af6c4c8341

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 6.2 years (2,271 days).

Biospecimens (3 samples)
- Sample 0DSWYP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSWZ0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSWZ7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
